Somatic mutation profile of tumor specimen TCGA-06-0221-01A (aliquot TCGA-06-0221-01A-01D-1491-08) from TCGA case TCGA-06-0221, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 31.0 years (11,333 days).
Specimen TCGA-06-0221-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a86c8eb7-0b17-44fb-91cc-62082cc77317.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0221-10A (Blood Derived Normal), aliquot TCGA-06-0221-10A-01D-1491-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7cff630c-060e-4542-b25e-a0308c0a7ac3

The open-access MAF lists 31 somatic variants for this specimen: 23 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 19, Silent 8, Frame Shift Del 2, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- F5 | c.6304C>T p.R2102C | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs118203910, CM030037, COSV63121893; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- IDH1 | c.394C>G p.R132G | Missense Mutation (SNP) | VAF 47/131 reads (36%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS16 | c.604del p.H202Tfs*20 | Frame Shift Del (DEL) | VAF 36/142 reads (25%) | catalogued as COSV56987127; called by mutect2, pindel, varscan2
- ANGPT1 | c.767A>G p.D256G | Missense Mutation (SNP) | VAF 13/228 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.284); catalogued as rs1426733536, COSV52447728; called by muse, mutect2
- ATRX | c.529C>T p.Q177* | Nonsense Mutation (SNP) | VAF 72/86 reads (84%) | catalogued as COSV64869924; called by muse, mutect2, varscan2
- CCDC149 | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1268753550, COSV60878484; called by muse, mutect2, varscan2
- CFAP57 | c.1432T>A p.S478T | Missense Mutation (SNP) | VAF 101/269 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV63016765; called by muse, mutect2, varscan2
- DAO | c.5G>A p.R2H | Missense Mutation (SNP) | VAF 8/129 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.026); catalogued as rs142698254; called by muse, mutect2
- KMT2B | c.2108G>A p.S703N | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as COSV52891499; called by muse, mutect2, varscan2
- KRT1 | c.662C>A p.S221Y | Missense Mutation (SNP) | VAF 61/137 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV52868030; called by muse, mutect2, varscan2
- NCOA3 | c.3152G>T p.R1051I | Missense Mutation (SNP) | VAF 11/159 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.168); catalogued as COSV59070799; called by muse, mutect2
- OR2A14 | c.177C>A p.Y59* | Nonsense Mutation (SNP) | VAF 15/398 reads (4%) | catalogued as COSV68718446; called by muse, mutect2
- OR52K2 | c.692C>A p.A231D | Missense Mutation (SNP) | VAF 9/222 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.661); catalogued as COSV57835488; called by muse, mutect2
- PPAN-P2RY11 | c.1910C>T p.P637L | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs200840736, COSV53452285; called by muse, mutect2, varscan2
- RSPO3 | c.313T>A p.C105S | Missense Mutation (SNP) | VAF 66/153 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63151930; called by muse, mutect2, varscan2
- SALL1 | c.3067C>T p.H1023Y | Missense Mutation (SNP) | VAF 47/139 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV51760974; called by muse, mutect2, varscan2
- SIGLEC11 | c.1485G>T p.E495D | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.741); catalogued as COSV70222075; called by muse, mutect2, varscan2
- SLCO6A1 | c.709A>G p.T237A | Missense Mutation (SNP) | VAF 113/264 reads (43%) | SIFT tolerated (0.49); PolyPhen benign (0.044); catalogued as COSV65812666; called by muse, mutect2, varscan2
- TRPM3 | c.2408T>A p.M803K (on ENST00000357533 / NM_001366142.2; = p.M646K on NM_020952.6) | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV62590186; called by muse, mutect2
- ZFP57 | c.985T>C p.S329P | Missense Mutation (SNP) | VAF 67/188 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV65306555; called by muse, mutect2, varscan2
- ZNF254 | c.1864A>G p.R622G | Missense Mutation (SNP) | VAF 128/210 reads (61%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as rs1244560554, COSV61643716; called by muse, mutect2, varscan2
- ZNF665 | c.465C>G p.N155K (on ENST00000600412; = p.N220K on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.097); catalogued as COSV67216328; called by muse, mutect2
- TP53 | c.417_418del p.K139Nfs*9 | Frame Shift Del (DEL) | VAF 48/75 reads (64%) | called by mutect2, pindel, varscan2
- FCRL1 | c.984C>T p.Y328= | Silent (SNP) | VAF 40/119 reads (34%) | catalogued as rs200953593; called by muse, mutect2, varscan2
- KCNU1 | c.495G>A p.K165= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as COSV67757887; called by muse, mutect2, varscan2
- KDM3A | c.1857G>A p.K619= | Silent (SNP) | VAF 25/314 reads (8%) | catalogued as COSV57223475; called by muse, mutect2
- MGA | c.7560A>G p.K2520= (on ENST00000219905 / NM_001164273.1; = p.K2311= on NM_001080541.2) | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV54958369; called by muse, mutect2, varscan2
- PLEKHG1 | c.1635C>T p.S545= | Silent (SNP) | VAF 13/94 reads (14%) | catalogued as rs1562561204, COSV62049125; called by muse, mutect2, varscan2
- SLC4A4 | c.1362G>A p.A454= (on ENST00000264485 / NM_001098484.3; = p.A410= on NM_003759.4) | Silent (SNP) | VAF 26/411 reads (6%) | catalogued as rs754788772, COSV52623410; called by muse, mutect2
- TLL2 | c.1587G>A p.T529= | Silent (SNP) | VAF 39/97 reads (40%) | catalogued as rs151335014; called by muse, mutect2, varscan2
- TTN | c.87036C>T p.T29012= (on ENST00000591111; = p.T21588= on NM_003319.4) | Silent (SNP) | VAF 11/133 reads (8%) | catalogued as COSV60085571, COSV60189736; called by muse, mutect2
